Somatic mutation profile of tumor specimen TCGA-BQ-5879-01A (aliquot TCGA-BQ-5879-01A-11D-1589-08) from TCGA case TCGA-BQ-5879, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 32.5 years (11,862 days).
Specimen TCGA-BQ-5879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b98f35f0-6477-45c1-b280-d8b5b0992cd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5879-11A (Solid Tissue Normal), aliquot TCGA-BQ-5879-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baca77ad-9642-4da2-b130-9c458d7bf430

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV66059524; called by muse, mutect2, varscan2
- DCAF7 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV59000960; called by muse, mutect2
- MIDEAS | c.1961A>G p.Y654C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54092855; called by muse, mutect2, varscan2
- NELL2 | c.1310A>G p.Y437C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1309074093, COSV61569608; called by muse, mutect2, varscan2
- NUP88 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs775368499, COSV56702979; called by muse, mutect2, varscan2
- POP1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62891941; called by muse, mutect2, varscan2
- RAB3GAP1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV51478954; called by muse, mutect2, varscan2
- RTL9 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71825411; called by muse, mutect2, varscan2
- RYR1 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1364757414, COSV100615646, COSV62089865; called by muse, mutect2
- RYR3 | c.2318G>T p.G773V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66778937, COSV66809808; called by muse, mutect2, varscan2
- SF3B3 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV56785423; called by muse, mutect2, varscan2
- SLC5A6 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs199587675, COSV60158352; called by muse, mutect2, varscan2
- SSX1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as rs782680032, COSV65354964; called by muse, mutect2
- TTN | c.76874C>A p.A25625E (on ENST00000591111; = p.A18201E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV59901739; called by muse, mutect2, varscan2
- ZNF175 | c.1937T>C p.L646P | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV51794110; called by muse, mutect2, varscan2
- ACTR1B | c.533_536del p.H178Pfs*140 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- LSM14A | c.938_939del p.E313Vfs*3 | Frame Shift Del (DEL) | VAF 46/146 reads (32%) | called by pindel, varscan2
- AC127029.3 | c.687C>A p.V229= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV60110303; called by muse, mutect2, varscan2
- IGKV2D-29 | c.189G>A p.Q63= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV101534365; called by muse, mutect2, varscan2
- LMNA | c.918C>T p.L306= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV61542011; called by muse, mutect2, varscan2
- MYH3 | c.426C>T p.G142= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs577513442, COSV56861310; called by muse, mutect2, varscan2
- PTPRA | c.1011C>T p.V337= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV53778607; called by muse, mutect2, varscan2
- SLC12A7 | c.198G>A p.G66= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as rs765067908, COSV53754719; called by muse, mutect2, varscan2
- USP26 | c.2028T>G p.P676= | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as COSV63708106; called by muse, mutect2, varscan2
